Somatic mutation profile of tumor specimen TCGA-QQ-A5VC-01A (aliquot TCGA-QQ-A5VC-01A-31D-A32I-09) from TCGA case TCGA-QQ-A5VC, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 63.9 years (23,357 days).
Specimen TCGA-QQ-A5VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b382764f-bd93-4e93-8602-657e0d80464d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5VC-10A (Blood Derived Normal), aliquot TCGA-QQ-A5VC-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47d7e46e-7821-4f32-a09b-ea821e1c9db3

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, 3'Flank 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RXRA | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV99738766; called by muse, mutect2, varscan2
- AHNAK | c.15520A>G p.N5174D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.431); catalogued as rs763164549, COSV99947653; called by muse, mutect2, varscan2
- APEH | c.1227C>A p.S409R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99610802; called by muse, mutect2, varscan2
- ATP2B1 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99665745; called by muse, mutect2, varscan2
- BPIFB3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100972358; called by muse, mutect2, varscan2
- C6 | c.2287A>G p.K763E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99667137; called by muse, mutect2, varscan2
- CDH5 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs543649916, COSV58518361; called by muse, mutect2, varscan2
- DGKG | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753336390, COSV99403412; called by muse, mutect2, varscan2
- EPM2A | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs138798058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOC7 | c.2116G>A p.V706M (on ENST00000335146 / NM_001145297.4; = p.V624M on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs778698782, COSV58035070; called by muse, mutect2, varscan2
- FANCC | c.154T>A p.L52M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100002485; called by muse, mutect2, varscan2
- FRMPD2 | c.3716A>G p.Q1239R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100563849; called by muse, mutect2, varscan2
- H2AC11 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100345759; called by muse, mutect2, varscan2
- HNRNPA3 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV101182920; called by muse, mutect2, varscan2
- HOXA4 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100415485; called by muse, mutect2, varscan2
- KDM5C | c.3456G>C p.E1152D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV100949202; called by muse, mutect2, varscan2
- KLK13 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99335303; called by muse, mutect2, varscan2
- KPRP | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as rs768264463, COSV64221752; called by muse, varscan2
- MAGI1 | c.3730T>A p.S1244T | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100441158; called by muse, mutect2, varscan2
- MGAM | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374646574; called by muse, mutect2, varscan2
- MGAT4C | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.023); catalogued as COSV100152987, COSV59832339; called by muse, mutect2, varscan2
- MS4A2 | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99627303; called by muse, mutect2, varscan2
- MYH10 | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1159027232, COSV99345298; called by muse, mutect2, varscan2
- NAV3 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99891380; called by muse, mutect2, varscan2
- NLRP11 | c.1619C>G p.T540R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374796362, COSV100789747; called by mutect2, varscan2
- NPTX1 | c.758T>C p.F253S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100151028; called by muse, mutect2, varscan2
- PARP8 | c.2393A>C p.D798A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV55866888, COSV99891533; called by muse, mutect2, varscan2
- PCDH17 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100931677, COSV64973606; called by muse, mutect2, varscan2
- PIWIL1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99806444; called by muse, mutect2, varscan2
- PKHD1 | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100583220; called by muse, mutect2, varscan2
- RAP2C | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747342; called by muse, mutect2, varscan2
- RFTN1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV100489365; called by muse, mutect2
- RIMBP3 | c.3031A>G p.I1011V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.373); catalogued as rs1466431558; called by muse, mutect2, varscan2
- ROBO2 | c.3085G>T p.D1029Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100166980, COSV59914013; called by muse, mutect2, varscan2
- TMEM131L | c.3955C>T p.R1319W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs148556115; called by muse, varscan2
- TOP2B | c.271A>G p.M91V (on ENST00000264331 / NM_001330700.2; = p.M86V on NM_001068.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99979747; called by muse, mutect2, varscan2
- TTN | c.10244C>A p.T3415K (on ENST00000591111; = p.T3369K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | PolyPhen benign (0.017); catalogued as COSV100614536, COSV60169373; called by muse, mutect2, varscan2
- VPS13D | c.7834G>A p.V2612I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs139303925, COSV50668432; called by muse, mutect2, varscan2
- ZCCHC9 | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV99562659; called by muse, mutect2, varscan2
- ZFP42 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.261); catalogued as COSV100478993, COSV58819789; called by muse, mutect2, varscan2
- NF1 | c.7012_7032del p.E2339_L2345del (on ENST00000358273 / NM_001042492.3; = p.E2318_L2324del on NM_000267.3) | In Frame Del (DEL) | VAF 22/27 reads (81%) | called by mutect2, pindel*, varscan2*
- ACKR4 | c.669A>G p.T223= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs3911405; called by mutect2, varscan2
- AKR7L | c.856C>T p.L286= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV101334288, COSV101334372; called by muse, mutect2, varscan2
- AMPD2 | c.2328C>T p.I776= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV99857760; called by muse, mutect2, varscan2
- CYFIP1 | c.945G>T p.L315= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- EOGT | c.1524T>C p.A508= (on ENST00000383701 / NM_001278689.2; = p.A424= on NM_173654.3) | Silent (SNP) | VAF 74/82 reads (90%) | catalogued as COSV99808907; called by muse, mutect2, varscan2
- HOOK1 | c.2118G>A p.A706= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as rs754738109, COSV64619571; called by muse, mutect2, varscan2
- MYO6 | c.3243T>C p.G1081= (on ENST00000369981; = p.G1071= on NM_004999.4) | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100889357; called by muse, mutect2, varscan2
- OR9K2 | c.933G>A p.L311= (on ENST00000305377; = p.L289= on NM_001005243.1) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs751149189, COSV100543849, COSV59532834; called by muse, mutect2, varscan2
- PASK | c.3567G>T p.L1189= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99299506; called by muse, mutect2, varscan2
- PCF11 | c.3000C>T p.V1000= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs763387572, COSV53536049; called by muse, mutect2, varscan2
- RBM19 | c.1461T>C p.D487= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99926137; called by muse, mutect2, varscan2
- RPTN | c.1530C>T p.H510= | Silent (SNP) | VAF 90/402 reads (22%) | catalogued as COSV60166649; called by muse, mutect2, varscan2
- SHANK2 | c.4350G>T p.S1450= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53595060, COSV99574185; called by muse, mutect2, varscan2
- SS18 | c.1188A>G p.G396= (on ENST00000415083 / NM_001007559.3; = p.G365= on NM_005637.3) | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99294166; called by muse, mutect2, varscan2
- ZNF671 | c.81G>A p.P27= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100235062; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792051 C>T | 3'Flank (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
